TARGET case TARGET-15-SJMPAL040037 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9519ed65-f851-4825-aba7-3d52a2331da9

Demographics
Sex at birth: male; Age at index: 15 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 15.3 years (5,594 days); Year of diagnosis: 2010; Days to last follow up: 963 days (2.6 years).

Follow-up (1 entry)
- Days to follow up: 963 days (2.6 years); Event-free: no event (relapse, second malignancy or death) recorded through day 963; Year of follow up: 2013.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 9.3 ×10³/µL.

Biospecimens (7 samples)
- Samples TARGET-15-SJMPAL040037-09A, TARGET-15-SJMPAL040037-09A.1, TARGET-15-SJMPAL040037-09A.2, TARGET-15-SJMPAL040037-09A.3, TARGET-15-SJMPAL040037-09A.4, TARGET-15-SJMPAL040037-09B (6 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL040037-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 963
- Protocol: AIEOP
- WBC at Diagnosis: 9.3
- Initial Therapy: ALL
- WHO ALAL Classification: T/M
- WHO Dx: T/M
